Somatic mutation profile of tumor specimen MP2PRT-PAVDNN-TMP1-A (aliquot MP2PRT-PAVDNN-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PAVDNN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,357 days).
Specimen MP2PRT-PAVDNN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a4898c1-d603-4715-991d-d915d9981746.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVDNN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVDNN-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b2fc81d-41c5-46b8-99f6-967f69dd8a02

The open-access MAF lists 36 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 23, Silent 7, Frame Shift Ins 3, Splice Region 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMC8 | c.1405G>A p.A469T (on ENST00000469044 / NM_001363941.2; = p.A455T on NM_015396.6) | Missense Mutation (SNP) | VAF 16/371 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1429678107; called by muse, mutect2
- DLG2 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 61/349 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs150156552, COSV54627336; called by muse, mutect2, varscan2
- DYNC2H1 | c.9124G>T p.G3042C | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1489250316; called by muse, varscan2
- GFAP | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 34/361 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1333731884, COSV53651220; called by muse, mutect2, varscan2
- ICE2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.013); catalogued as rs201440459, COSV99831861; called by muse, mutect2
- IGHV3-43 | c.353del p.D118del | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | catalogued as rs772831082; called by pindel*, varscan2
- LETM2 | c.979G>C p.D327H (on ENST00000379957 / NM_001286819.2; = p.D232H on NM_144652.3) | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99907602; called by muse, mutect2, varscan2
- LINGO1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 149/314 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1333972993, COSV62437604; called by muse, mutect2, varscan2
- MROH2B | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 43/313 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV68183191, COSV68185644; called by muse, mutect2, varscan2
- PRR23C | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 22/454 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as rs1412832160, COSV68827566; called by muse, mutect2
- SLC8A3 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 99/339 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs766322163, COSV63526605; called by muse, mutect2, varscan2
- TMEM94 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs748943433; called by muse, mutect2, varscan2
- YIPF4 | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV99480108; called by muse, mutect2, varscan2
- ZNF780B | c.607C>G p.Q203E | Missense Mutation (SNP) | VAF 10/310 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as rs759277704; called by muse, mutect2
- AKAP6 | c.4246G>A p.E1416K | Missense Mutation (SNP) | VAF 14/443 reads (3%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.197); called by muse, mutect2
- CARD19 | c.182G>T p.R61L | Missense Mutation (SNP) | VAF 164/361 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- CATSPER4 | c.555C>T p.L185= | Splice Region (SNP) | VAF 21/207 reads (10%) | called by muse, mutect2, varscan2
- CMKLR1 | c.541G>T p.A181S (on ENST00000312143 / NM_001142344.2; = p.A179S on NM_004072.3) | Missense Mutation (SNP) | VAF 82/301 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CRACD | c.1158G>T p.L386F | Missense Mutation (SNP) | VAF 96/407 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.051); called by muse, varscan2
- DCAF1 | c.2137C>T p.Q713* | Nonsense Mutation (SNP) | VAF 39/294 reads (13%) | called by muse, mutect2, varscan2
- DEPDC4 | c.746A>G p.H249R | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- DNAJC6 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FAM47A | c.1433C>G p.P478R | Missense Mutation (SNP) | VAF 40/594 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.093); called by muse, mutect2
- FAT1 | c.13720G>C p.E4574Q | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GDF6 | c.250dup p.E84Gfs*26 | Frame Shift Ins (INS) | VAF 50/434 reads (12%) | called by pindel, varscan2
- IGHV3-33 | chr14:106359785 ACTGTGTCTCTCGCACAGTAAT>CCCAGGG | Missense Mutation (DEL) | VAF 52/70 reads (74%) | called by pindel, varscan2*
- SYK | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.33523delinsAA p.E11175Kfs*10 (on ENST00000591111; = p.E10248Kfs*10 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 49/385 reads (13%) | called by pindel, varscan2*
- UBA2 | c.317dup p.R107Pfs*12 | Frame Shift Ins (INS) | VAF 47/184 reads (26%) | called by mutect2, pindel, varscan2
- ADAR | c.348G>A p.R116= | Silent (SNP) | VAF 15/407 reads (4%) | catalogued as COSV52714177; called by muse, mutect2
- FAT4 | c.7680C>T p.F2560= | Silent (SNP) | VAF 12/368 reads (3%) | called by muse, mutect2
- PXT1 | c.48C>G p.L16= | Silent (SNP) | VAF 10/292 reads (3%) | called by muse, mutect2
- RHNO1 | c.240A>G p.R80= | Silent (SNP) | VAF 110/261 reads (42%) | called by muse, mutect2, varscan2
- SEC31B | c.2142G>A p.L714= | Silent (SNP) | VAF 34/211 reads (16%) | called by muse, mutect2, varscan2
- TMEM271 | c.408C>T p.F136= | Silent (SNP) | VAF 50/420 reads (12%) | called by muse, mutect2, varscan2
- TRIM2 | c.1158C>T p.N386= (on ENST00000437508; = p.N413= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 46/259 reads (18%) | catalogued as rs202177942; called by muse, mutect2, varscan2
